Gene-level copy-number profile of specimen HCM-CSHL-0155-C50-85D from HCMI case HCM-CSHL-0155-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 49.0 years (17,880 days).
Specimen HCM-CSHL-0155-C50-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 17.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d16b4dd-d617-4460-b3fe-d0adbea48a28.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0155-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/b8edc1ac-6ffc-4187-afe0-652b1a4f9919

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,234; copy number 2: 10,633; copy number 3: 28,461; copy number 4: 12,475; copy number 5: 1,993; copy number 6: 1,642; copy number 7: 376; copy number 8: 108; copy number 9: 193; copy number 10: 73; copy number 11: 24; copy number 12: 87; copy number 14: 35; copy number 15: 3; copy number 16: 2; copy number 17: 15; copy number 18: 9; copy number 24: 4; copy number 72: 16; copy number 94: 8.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 953 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:50,435,380–50,435,486, 1 gene, copy number 7: RNU6-1091P.
- chr7:63,621,090–63,790,098, 5 genes, copy number 7: MIR4283-2, AC006015.1, AC079355.1, CICP24, AC079355.2.
- chr8:36,784,324–39,417,378, 73 genes, copy number 8–9 (broad region; genes not listed).
- chr8:39,522,976–41,650,817, 37 genes, copy number 7: AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3.
- chr8:42,271,302–46,550,802, 48 genes, copy number 7–17: IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.2, AC139365.2, AC139365.1, AC118650.1, HSPA8P13.
- chr8:61,500,556–67,407,072, 94 genes, copy number 7–14 (within-gene range 6–14) (broad region; genes not listed).
- chr8:76,681,239–76,867,281, 1 gene, copy number 9 (within-gene range 4–9): ZFHX4.
- chr8:76,904,591–77,014,028, 4 genes, copy number 9: AC023200.1, MIR3149, PEX2, HIGD1AP18.
- chr8:88,032,011–106,981,571, 328 genes, copy number 7–18 (within-gene range 7–21) (broad region; genes not listed).
- chr8:112,148,742–113,616,958, 8 genes, copy number 8: RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC103993.1.
- chr8:119,214,625–120,056,201, 19 genes, copy number 8–10 (within-gene range 2–10): MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1.
- chr8:126,474,189–127,482,139, 16 genes, copy number 9–12: AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr8:144,049,079–145,066,685, 73 genes, copy number 9 (broad region; genes not listed).
- chr9:60,914,407–61,231,863, 10 genes, copy number 8: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1.
- chr10:46,286,345–46,537,864, 9 genes, copy number 7: ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr10:49,419,277–49,710,261, 6 genes, copy number 8: AL138760.1, ERCC6, HMGB1P50, CHAT, SLC18A3, C10orf53.
- chr10:70,052,544–70,602,759, 16 genes, copy number 72: MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2, RPS25P9, PPA1, NPFFR1, LRRC20, CEP57L1P1, EIF4EBP2, NODAL, AC022532.1, PALD1, YY1P1, PRF1.
- chr17:19,296,596–21,002,276, 100 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr17:37,609,739–39,944,734, 97 genes, copy number 7–94 (broad region; genes not listed).
- chr17:50,962,174–51,171,744, 5 genes, copy number 7: SPAG9, AC005920.2, NME1, NME1-NME2, NME2.
- chr17:51,630,313–52,160,017, 1 gene, copy number 7 (within-gene range 6–7): CA10.
- chr17:52,390,515–52,535,701, 1 gene, copy number 17: LINC01982.
- chr17:71,620,978–71,621,436, 1 gene, copy number 7: MYL6P5.

Autosomal genes at a single copy (total copy number 1): 1,529. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
